Gene-level copy-number profile of tumor specimen TCGA-WB-A815-01A from TCGA case TCGA-WB-A815, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 68.1 years (24,859 days).
Specimen TCGA-WB-A815-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PCPG.5f0b998d-645a-4819-9d00-1b10f3244654.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WB-A815-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5ca726b3-ec0e-4b63-b6bb-7e9c2977e7d8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,015; copy number 2: 44,412; copy number 3: 4,393.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WB-A815-01A-11D-A35H-01): tumor purity 0.73, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 11,015. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
